Gene-level copy-number profile of tumor specimen ALCH-B485-TTP1-A from ALCHEMIST case ALCH-B485, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: female; Primary diagnosis: Adenocarcinoma, NOS; Age at diagnosis: 67.2 years (24,558 days).
Specimen ALCH-B485-TTP1-A: Sample type: FFPE Scrolls; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 5e0c6751-0d28-4663-a2b0-ba9b6a33b420.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator ALCH-B485-NB1-A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 2,222 have no estimate.
https://portal.gdc.cancer.gov/files/cd15afeb-74ee-4ff6-a6a7-ed253d847fbd

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 47; copy number 1: 3,745; copy number 2: 54,468; copy number 3: 141.

Homozygous deletions (total copy number 0; autosomes only): 47 genes in 11 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:62,189,131–62,212,328, 5 genes: PIGPP2, RPS15AP7, L1TD1, AL162739.1, Y_RNA.
- chr2:44,921,077–44,968,762, 12 genes: LINC01833, AC012354.9, AC012354.2, AC012354.7, AC012354.5, AC012354.8, AC012354.4, AC012354.3, AC012354.6, SIX3-AS1, SIX3, AC012354.1.
- chr2:117,859,427–117,934,942, 1 gene (within-gene range 0–2): HTR5BP.
- chr6:17,381,367–17,382,120, 1 gene: AL034372.1.
- chr7:66,485,095–66,592,397, 5 genes (within-gene range 0–2): AC008267.6, GS1-124K5.4, AC008267.1, AC008267.3, AC006001.3.
- chr11:48,880,111–48,908,946, 4 genes: AC027369.6, AC027369.3, AC027369.4, AC027369.5.
- chr15:75,674,322–75,727,688, 4 genes (within-gene range 0–2): CSPG4, AC105020.4, AC105020.1, ODF3L1.
- chr17:20,436,337–20,528,687, 10 genes: NOS2P3, LGALS9B, TNPO1P3, YWHAEP3, KRT16P5, KRT16P3, AC015818.7, KRT17P6, KRT17P7, AC015818.6.
- chr17:41,619,442–41,624,842, 1 gene: KRT17.
- chr20:45,306,840–45,317,824, 1 gene (within-gene range 0–2): RBPJL.
- chr22:43,038,585–43,092,524, 3 genes: TTLL1-AS1, TTLL1, AL022237.1.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): none.

Autosomal genes at a single copy (total copy number 1): 3,737. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
